Gene-level copy-number profile of tumor specimen TCGA-BF-AAOX-01A from TCGA case TCGA-BF-AAOX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 83.0 years (30,318 days).
Specimen TCGA-BF-AAOX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.cfac8e28-7211-4a6f-9400-6ddca09da915.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BF-AAOX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2d1b7af3-bff0-4144-9529-094d11be8934

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,983; copy number 2: 45,519; copy number 3: 6,936; copy number 4: 341; copy number 5: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BF-AAOX-01A-11D-A396-01): tumor purity 0.68, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:69,577,251–71,871,750, 20 genes, copy number 5 (within-gene range 4–5): LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1.
- chr18:4,459,230–4,459,458, 1 gene, copy number 5: ELOCP27.

Autosomal genes at a single copy (total copy number 1): 4,596. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
